Gene-level copy-number profile of tumor specimen TCGA-AR-A1AY-01A from TCGA case TCGA-AR-A1AY, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 65.5 years (23,927 days).
Specimen TCGA-AR-A1AY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.dab4207f-5e33-4cbb-81af-b3f005c74c16.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A1AY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/271be44a-52b9-421c-8be8-893ff086f44d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 23,897; copy number 2: 28,071; copy number 3: 4,801; copy number 4: 2,944; copy number 5: 83; copy number 6: 2; copy number 11: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A1AY-01A-21D-A12N-01): tumor purity 0.79, ploidy 1.83, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,751,512–87,971,930, 7 genes (within-gene range 0–1): ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3.
- chr15:71,822,291–72,118,577, 1 gene (within-gene range 0–1): MYO9A.
- chr15:71,972,206–72,197,787, 7 genes (within-gene range 0–1): AC022872.1, EIF5A2P1, RNU2-65P, SENP8, AC020779.1, AC020779.2, GRAMD2A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 89 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:115,556,826–115,606,768, 4 genes, copy number 11: ELOCP20, CNOT7P2, AL592436.2, RN7SL420P.
- chr8:43,672,823–43,674,591, 2 genes, copy number 6: AC139365.2, AC139365.1.
- chr8:127,289,817–127,742,951, 8 genes, copy number 5: CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr8:127,795,962–127,796,028, 1 gene, copy number 5: MIR1204.
- chr18:60,495,868–65,448,167, 63 genes, copy number 5 (broad region; genes not listed).
- chr20:49,113,339–49,299,600, 11 genes, copy number 5: STAU1, ARPC3P1, DDX27, ZNFX1, ZFAS1, AL049766.2, SNORD12C, AL049766.1, SNORD12B, AL049766.3, SNORD12.

Autosomal genes at a single copy (total copy number 1): 21,476. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
